Somatic mutation profile of tumor specimen ALCH-B487-TTP1-A (aliquot ALCH-B487-TTP1-A-1-0-D-A80E-36) from ALCHEMIST case ALCH-B487, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 55.2 years (20,176 days).
Specimen ALCH-B487-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bd68619f-0f29-4c5c-8c71-8759cba5b3fa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B487-NB1-A (Blood Derived Normal), aliquot ALCH-B487-NB1-A-1-0-D-A80E-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dd784bbf-2443-4bbe-8db3-98e30aaa77ab

The open-access MAF lists 442 somatic variants for this specimen: 302 protein-altering or splice-affecting, 91 silent, 49 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 260, Silent 91, Nonsense Mutation 19, Intron 19, Splice Site 14, RNA 10, 5'Flank 7, 5'UTR 6, Frame Shift Del 4, 3'UTR 4, Splice Region 3, 3'Flank 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.388C>T p.R130* | Nonsense Mutation (SNP) | VAF 46/326 reads (14%) | hotspot (GDC flag); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.1010G>T p.R337L | Missense Mutation (SNP) | VAF 19/112 reads (17%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs121912664, CM012663, CM104660, COSV52665150, COSV52691988, COSV52828545; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.715A>G p.N239D | Missense Mutation (SNP) | VAF 29/166 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs876660807, COSV52664075, COSV52685174, COSV52979974, COSV53345856; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- A2M | c.1792C>A p.R598S | Missense Mutation (SNP) | VAF 38/214 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV59388808; called by muse, mutect2, varscan2
- ABCA7 | c.667G>A p.A223T | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.054); catalogued as rs747694809; called by muse, mutect2, varscan2
- ABLIM3 | c.91A>G p.K31E | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); catalogued as rs777942011; called by muse, mutect2, varscan2
- ADAMTS12 | c.907G>C p.E303Q | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.374); catalogued as COSV100710901, COSV61276249, COSV61280837; called by muse, mutect2, varscan2
- ADAT2 | c.388C>T p.R130* | Nonsense Mutation (SNP) | VAF 44/297 reads (15%) | catalogued as rs773519162, COSV52793296; called by muse, mutect2, varscan2
- AMER3 | c.2516G>T p.R839L | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs377081234; called by muse, mutect2, varscan2
- ANKFN1 | c.1315C>G p.R439G | Missense Mutation (SNP) | VAF 16/146 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59442842; called by muse, mutect2, varscan2
- ASPG | c.192-4G>A | Splice Region (SNP) | VAF 19/93 reads (20%) | catalogued as rs564677939; called by muse, mutect2, varscan2
- ATAD3C | c.917G>T p.R306L | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV101112622, COSV66482135; called by muse, mutect2, varscan2
- CCDC40 | c.1151G>A p.R384H | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as rs185083705, COSV53899963; called by muse, mutect2
- CD200 | c.863G>A p.R288Q (on ENST00000473539 / NM_001004196.3; = p.R263Q on NM_005944.7 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 47/157 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs759531262; called by muse, mutect2, varscan2
- CDH11 | c.575G>T p.G192V | Missense Mutation (SNP) | VAF 31/197 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV51753330, COSV99217031; called by muse, mutect2, varscan2
- CELF4 | c.904C>T p.L302F | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs1468223303; called by muse, varscan2
- CELSR3 | c.3631G>C p.E1211Q | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.737); catalogued as rs775450200; called by muse, mutect2, varscan2
- CEP43 | c.967A>G p.K323E | Missense Mutation (SNP) | VAF 18/143 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.118); catalogued as rs765053714; called by muse, mutect2, varscan2
- CFHR4 | c.216C>A p.C72* (on ENST00000367416 / NM_001201551.2; = p.C73* on NM_006684.5) | Nonsense Mutation (SNP) | VAF 51/153 reads (33%) | catalogued as rs1246360223, COSV52228741; called by muse, mutect2, varscan2
- COL3A1 | c.622C>A p.Q208K | Missense Mutation (SNP) | VAF 41/280 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.388); catalogued as rs746358771; called by muse, mutect2, varscan2
- CYP11B2 | c.101C>T p.T34M | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.146); catalogued as rs753988592, COSV59995329; called by muse, mutect2, varscan2
- EDAR | c.106T>C p.Y36H | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.44); catalogued as COSV51504863; called by muse, mutect2
- EYS | c.2741G>T p.C914F | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.311); catalogued as COSV65512772; called by muse, mutect2, varscan2
- EYS | c.2494C>A p.Q832K | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV101009122; called by muse, mutect2
- FAM135B | c.2065G>C p.E689Q | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52736573; called by muse, mutect2, varscan2
- FAT3 | c.2020G>A p.G674R | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs377153421; called by muse, mutect2, varscan2
- FHOD1 | c.950C>T p.A317V | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs1434780234, COSV50758867, COSV50761191; called by mutect2, varscan2
- FSIP1 | c.690G>C p.L230F | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.9); catalogued as COSV63223404; called by muse, mutect2
- FUT7 | c.332C>T p.P111L | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as rs749157642; called by muse, mutect2, varscan2
- GAREM1 | c.487C>A p.L163I | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52514181; called by muse, mutect2, varscan2
- GLRA4 | c.578-1G>C p.X193_splice | Splice Site (SNP) | VAF 6/11 reads (55%) | catalogued as rs758346320, COSV65455715; called by muse, mutect2, varscan2
- GMNC | c.454G>C p.E152Q | Missense Mutation (SNP) | VAF 19/165 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.05); catalogued as COSV71249002; called by muse, varscan2
- GRM8 | c.1880C>A p.T627K | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.522); catalogued as COSV58834505; called by muse, mutect2, varscan2
- HAUS5 | c.1596G>T p.W532C | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.35); catalogued as rs765660968; called by muse, mutect2, varscan2
- HBZ | c.75del p.I25Mfs*47 | Frame Shift Del (DEL) | VAF 23/97 reads (24%) | catalogued as COSV53317105; called by mutect2, varscan2
- ICAM2 | c.706T>C p.S236P | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV56744053; called by muse, mutect2, varscan2
- ITIH5 | c.524G>T p.S175I | Missense Mutation (SNP) | VAF 37/195 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV56904734; called by muse, mutect2, varscan2
- JUNB | c.157C>T p.P53S | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.023); catalogued as rs570057440; called by muse, mutect2, varscan2
- KEAP1 | c.562G>A p.A188T | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); catalogued as rs143219271; called by muse, mutect2, varscan2
- KIF26A | c.500C>T p.T167M | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs746053979; called by muse, varscan2
- LCP1 | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV100549862; called by muse, mutect2
- LELP1 | c.247C>A p.P83T | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.469); catalogued as COSV64202741; called by muse, mutect2
- LIPH | c.886+1G>A p.X296_splice | Splice Site (SNP) | VAF 10/116 reads (9%) | catalogued as rs1031193982, COSV56184563; called by muse, mutect2
- LRP1B | c.4191G>C p.W1397C | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV101256364; called by muse, mutect2
- LRP1B | c.1693G>C p.A565P | Missense Mutation (SNP) | VAF 25/213 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.753); catalogued as COSV67203627; called by muse, mutect2, varscan2
- MAP4K4 | c.1490G>A p.R497Q | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.091); catalogued as rs772128002, COSV56340169; called by muse, mutect2
- MGAM2 | c.3080C>T p.P1027L | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs770360499; called by muse, varscan2
- MIPOL1 | c.925C>G p.R309G | Missense Mutation (SNP) | VAF 12/194 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV59389869; called by muse, mutect2
- MLF2 | c.592C>T p.R198W | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1199547583; called by muse, mutect2, varscan2
- NAALADL2 | c.1205C>T p.A402V | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs370137851; called by muse, mutect2, varscan2
- NAV3 | c.2228G>T p.R743M | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57091477; called by muse, mutect2, varscan2
- NID2 | c.14G>A p.R5Q | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); catalogued as rs898391761; called by muse, mutect2, varscan2
- OR10G4 | c.851C>A p.P284H | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100305046; called by muse, mutect2
- OR1C1 | c.374C>T p.A125V | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs563143111, COSV68715361; called by muse, mutect2
- OR1J2 | c.121G>T p.G41W | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.623); catalogued as COSV58945298; called by muse, mutect2, varscan2
- OR2T4 | c.266C>G p.T89S | Missense Mutation (SNP) | VAF 39/217 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.125); catalogued as rs540150117, COSV63543895; called by muse, mutect2, varscan2
- OR52E8 | c.614G>A p.G205D | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV66214541; called by muse, mutect2, varscan2
- OSBPL1A | c.235G>A p.D79N | Missense Mutation (SNP) | VAF 20/128 reads (16%) | SIFT tolerated (0.75); PolyPhen probably damaging (0.996); catalogued as rs200701683; called by muse, mutect2, varscan2
- PCDHA4 | c.1436C>T p.A479V | Missense Mutation (SNP) | VAF 26/219 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as rs1181544885; called by muse, mutect2, varscan2
- PCDHB7 | c.1058C>A p.T353N | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.033); catalogued as rs1411935753, COSV50754871, COSV99177005; called by muse, mutect2, varscan2
- PCLO | c.5125G>T p.E1709* | Nonsense Mutation (SNP) | VAF 11/52 reads (21%) | catalogued as COSV61649687; called by muse, mutect2, varscan2
- PIWIL4 | c.2330G>A p.R777Q | Missense Mutation (SNP) | VAF 18/156 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs772647055; called by muse, mutect2, varscan2
- PLXNB2 | c.5174G>A p.R1725H | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.987); catalogued as rs772755944; called by muse, mutect2, varscan2
- PNMA3 | c.52C>G p.R18G | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as rs190348179; called by muse, mutect2, varscan2
- PTGS2 | c.752C>T p.T251I | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.272); catalogued as rs1318781700; called by muse, mutect2
- PTPRB | c.4540G>T p.E1514* | Nonsense Mutation (SNP) | VAF 23/117 reads (20%) | catalogued as COSV54237331; called by muse, mutect2, varscan2
- PTPRD | c.2984G>T p.R995L | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV61963346; called by muse, mutect2, varscan2
- RABEP2 | c.1027C>T p.Q343* | Nonsense Mutation (SNP) | VAF 11/43 reads (26%) | catalogued as rs11545703; called by muse, mutect2, varscan2
- RELN | c.5686G>T p.D1896Y | Missense Mutation (SNP) | VAF 29/169 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as COSV59023172; called by muse, mutect2, varscan2
- RHAG | c.682G>T p.A228S | Missense Mutation (SNP) | VAF 49/278 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV57704713; called by muse, mutect2, varscan2
- RIC8B | c.211C>T p.R71C | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750693295, COSV62695446; called by muse, mutect2, varscan2
- SCN8A | c.1531G>T p.D511Y | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV61992764; called by muse, mutect2, varscan2
- SIGLEC1 | c.1660G>A p.E554K | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.907); catalogued as rs572890740; called by muse, mutect2, varscan2
- SIGLEC5 | c.645G>A p.M215I | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV55781406; called by muse, mutect2, varscan2
- SLC25A39 | c.959_960del p.F320Cfs*22 (on ENST00000377095 / NM_001143780.3; = p.F312Cfs*22 on NM_016016.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 18/65 reads (28%) | catalogued as rs1437215045; called by mutect2, pindel, varscan2
- SMAD4 | c.1140-2A>T p.X380_splice | Splice Site (SNP) | VAF 50/204 reads (25%) | catalogued as COSV61687665, COSV61688614; called by muse, mutect2, varscan2
- SPTBN5 | c.3660C>A p.F1220L | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); catalogued as COSV58017681; called by muse, mutect2, varscan2
- SRRM2 | c.337G>A p.G113R | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.96); catalogued as COSV57069276; called by muse, mutect2, varscan2
- SRRT | c.1637C>T p.P546L | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.019); catalogued as rs1340315253; called by muse, mutect2
- SUCLG1 | c.679G>A p.G227R | Missense Mutation (SNP) | VAF 29/155 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757620469; called by muse, mutect2, varscan2
- TBC1D30 | c.1852C>T p.R618* (on ENST00000542120; = p.R455* on NM_015279.2 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 24/174 reads (14%) | catalogued as rs1330542816, COSV57486095; called by muse, mutect2, varscan2
- TCL1A | c.84C>A p.D28E | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200322588; called by muse, mutect2, varscan2
- TDRD12 | c.441-1G>T p.X147_splice | Splice Site (SNP) | VAF 7/56 reads (13%) | catalogued as COSV70014331; called by muse, mutect2, varscan2
- TM2D1 | c.376G>T p.A126S | Missense Mutation (SNP) | VAF 18/196 reads (9%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); catalogued as COSV53908093; called by muse, mutect2
- TMEFF2 | c.101G>A p.R34H | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.197); catalogued as rs376482759, COSV55829970; called by muse, mutect2, varscan2
- TNR | c.133G>T p.V45L | Missense Mutation (SNP) | VAF 21/229 reads (9%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.058); catalogued as COSV99688348; called by muse, mutect2
- TPP1 | c.428G>A p.G143E | Missense Mutation (SNP) | VAF 30/205 reads (15%) | SIFT tolerated (0.9); PolyPhen probably damaging (0.921); catalogued as rs771835626; called by muse, mutect2, varscan2
- TPSD1 | c.179C>T p.P60L | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as rs1060282, COSV52973966; called by mutect2, varscan2
- TRMT44 | c.2083G>A p.E695K | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as rs1313675034; called by muse, mutect2, varscan2
- UNC13D | c.3127C>T p.P1043S | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.539); catalogued as rs780811495; called by muse, mutect2, varscan2
- USH2A | c.6724G>A p.E2242K | Missense Mutation (SNP) | VAF 64/163 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs375278546, COSV56333969; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WEE1 | c.923G>T p.G308V | Missense Mutation (SNP) | VAF 34/298 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55196275; called by muse, mutect2, varscan2
- WNK4 | c.3062C>T p.S1021L | Missense Mutation (SNP) | VAF 32/142 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.549); catalogued as rs1255414065; called by muse, mutect2, varscan2
- ZFR2 | c.1420G>C p.E474Q | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs201610307; called by muse, mutect2, varscan2
- ZNF609 | c.637G>T p.G213W | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58590051; called by muse, mutect2, varscan2
- ZP4 | c.349C>A p.H117N | Missense Mutation (SNP) | VAF 67/166 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV100850579, COSV63912987; called by muse, mutect2, varscan2
- ABCG5 | c.797T>C p.L266P | Missense Mutation (SNP) | VAF 48/157 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); called by muse, mutect2, varscan2
- ADAMTS2 | c.1898A>T p.Y633F | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- ADAMTS20 | c.1071C>G p.I357M | Missense Mutation (SNP) | VAF 25/132 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- ADAP1 | c.463G>C p.E155Q | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- ADCY7 | c.88C>T p.Q30* | Nonsense Mutation (SNP) | VAF 4/52 reads (8%) | called by muse, mutect2
- ADGB | c.3085A>T p.I1029F | Missense Mutation (SNP) | VAF 22/140 reads (16%) | SIFT tolerated (0.5); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- ADH6 | c.295T>C p.C99R | Missense Mutation (SNP) | VAF 19/185 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- AFG1L | c.738G>T p.R246S | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- AGMO | c.652C>A p.P218T | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ANKRD30B | c.1108G>T p.V370L | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- APEX2 | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 6/14 reads (43%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.056); called by muse, varscan2
- APOA5 | c.134A>T p.H45L | Missense Mutation (SNP) | VAF 34/155 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- APOB | c.2261T>G p.I754R | Missense Mutation (SNP) | VAF 64/211 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); called by muse, mutect2, varscan2
- ARFGAP1 | c.410C>T p.P137L | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.269); called by muse, mutect2
- ARHGAP26 | c.1391T>C p.L464P | Missense Mutation (SNP) | VAF 35/181 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARIH1 | c.1474G>C p.E492Q | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ARMC6 | c.1402C>A p.H468N (on ENST00000392336; = p.H443N on NM_033415.4) | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.567); called by muse, mutect2, varscan2
- ATF7IP | c.3619G>T p.A1207S | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- C17orf97 | c.451G>T p.V151F | Missense Mutation (SNP) | VAF 27/150 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.717); called by muse, mutect2, varscan2
- C7orf31 | c.328C>G p.Q110E | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.38); called by muse, mutect2, varscan2
- CACNA2D3 | c.1376G>T p.S459I | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- CALCA | c.227+1G>T p.X76_splice | Splice Site (SNP) | VAF 12/110 reads (11%) | called by muse, mutect2, varscan2
- CCDC178 | c.2347A>G p.K783E (on ENST00000383096 / NM_001105528.3; = p.K745E on NM_198995.3) | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.385); called by muse, mutect2, varscan2
- CD177 | c.916A>C p.S306R | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.052); called by mutect2, varscan2
- CDH8 | c.1513T>A p.C505S | Missense Mutation (SNP) | VAF 21/183 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- CENPE | c.7055C>A p.S2352Y | Missense Mutation (SNP) | VAF 49/434 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- CENPE | c.2863A>G p.T955A | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.1); called by muse, mutect2
- CEP162 | c.4111A>G p.T1371A | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CEP290 | c.156C>G p.F52L | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- CGAS | c.362G>C p.C121S | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2, varscan2
- CLGN | c.1753-2A>G p.X585_splice | Splice Site (SNP) | VAF 33/198 reads (17%) | called by muse, mutect2, varscan2
- COL6A1 | c.1499G>A p.G500E | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- COL7A1 | c.4216G>A p.G1406R | Missense Mutation (SNP) | VAF 44/154 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); called by muse, mutect2, varscan2
- COLEC12 | c.2113G>A p.G705R | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COX18 | c.196G>T p.V66F | Missense Mutation (SNP) | VAF 38/166 reads (23%) | SIFT tolerated (0.7); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CPEB2 | c.866G>C p.G289A | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- CRTAC1 | c.667C>A p.L223M | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- CSMD3 | c.10450C>A p.P3484T (on ENST00000297405 / NM_001363185.1; = p.P3315T on NM_052900.3) | Missense Mutation (SNP) | VAF 30/281 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- CTSK | c.662G>T p.C221F | Missense Mutation (SNP) | VAF 69/172 reads (40%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DAZAP2 | c.504G>T p.W168C | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DMRTA2 | c.889G>T p.G297C | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- DNAH5 | c.2775G>C p.L925F | Missense Mutation (SNP) | VAF 30/190 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- DTNA | c.689G>C p.R230P | Missense Mutation (SNP) | VAF 58/228 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EMILIN2 | c.2357C>T p.A786V | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.018); called by muse, mutect2
- F13A1 | c.272G>T p.R91L | Missense Mutation (SNP) | VAF 39/204 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- FAM169A | c.118C>T p.L40F | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.052); called by mutect2, varscan2
- FAM71B | c.475G>A p.D159N | Missense Mutation (SNP) | VAF 17/161 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.774); called by muse, mutect2, varscan2
- FARS2 | c.1127A>T p.Y376F | Missense Mutation (SNP) | VAF 48/290 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- FAT3 | c.6331A>G p.K2111E | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.075); called by muse, varscan2
- FCGBP | c.140C>A p.A47D | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.115); called by muse, mutect2
- FLG | c.5633C>A p.S1878Y | Missense Mutation (SNP) | VAF 103/212 reads (49%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.603); called by muse, varscan2
- FOXI1 | c.428G>C p.R143P | Missense Mutation (SNP) | VAF 49/241 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- FSHR | c.1325G>C p.C442S | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.612); called by muse, mutect2, varscan2
- FUS | c.1293-8C>T | Splice Region (SNP) | VAF 21/166 reads (13%) | called by muse, mutect2, varscan2
- GABBR1 | c.1632T>A p.G544= | Splice Region (SNP) | VAF 12/84 reads (14%) | called by muse, mutect2, varscan2
- GLCE | c.1732T>A p.Y578N | Missense Mutation (SNP) | VAF 35/198 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GLDC | c.2015A>C p.K672T | Missense Mutation (SNP) | VAF 60/197 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- GLIPR1 | c.529C>A p.P177T | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); called by muse, mutect2, varscan2
- GLRA1 | c.810C>G p.F270L | Missense Mutation (SNP) | VAF 44/301 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- GNB3 | c.821C>G p.T274R | Missense Mutation (SNP) | VAF 29/127 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- GOLGA8S | c.1078C>A p.L360M | Missense Mutation (SNP) | VAF 16/172 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPC5 | c.43C>G p.L15V | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- GPR179 | c.4425G>C p.Q1475H (on ENST00000621958; = p.Q1474H on NM_001004334.4) | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.269); called by muse, mutect2, varscan2
- GPRC6A | c.1455C>A p.H485Q | Missense Mutation (SNP) | VAF 29/248 reads (12%) | SIFT tolerated (0.61); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- GRM8 | c.2254T>C p.S752P | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.481); called by muse, mutect2
- HDX | c.1853A>T p.E618V | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- HECTD1 | c.5115G>T p.M1705I | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HECTD1 | c.5114T>A p.M1705K | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.019); called by muse, varscan2
- HEPACAM | c.427+1G>C p.X143_splice | Splice Site (SNP) | VAF 12/86 reads (14%) | called by muse, mutect2, varscan2
- HIC1 | c.917C>T p.P306L (on ENST00000322941 / NM_001098202.1; = p.P287L on NM_006497.4) | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HIF3A | c.1912+1G>T p.X638_splice (on ENST00000377670 / NM_152795.4; = p.X569_splice on NM_022462.4) | Splice Site (SNP) | VAF 4/12 reads (33%) | called by muse, varscan2
- HMGB2 | c.336G>C p.K112N | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.453); called by muse, mutect2, varscan2
- HMGCS2 | c.629G>A p.G210E | Missense Mutation (SNP) | VAF 23/127 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ICE1 | c.5455C>T p.Q1819* | Nonsense Mutation (SNP) | VAF 16/101 reads (16%) | called by muse, mutect2, varscan2
- IGF2BP2 | c.214G>T p.D72Y | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2
- IGHD | c.1284G>T p.K428N | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- IQCN | c.2508G>T p.M836I | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- KDM4E | c.1399G>T p.E467* | Nonsense Mutation (SNP) | VAF 45/253 reads (18%) | called by muse, mutect2, varscan2
- KIF21B | c.1792G>T p.G598C | Missense Mutation (SNP) | VAF 30/51 reads (59%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- KIF4B | c.2512C>T p.Q838* | Nonsense Mutation (SNP) | VAF 26/117 reads (22%) | called by muse, mutect2, varscan2
- KIR2DL1 | c.932C>G p.T311R | Missense Mutation (SNP) | VAF 20/353 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.461); called by muse, mutect2
- KIR2DS4 | c.296G>C p.R99T | Missense Mutation (SNP) | VAF 41/123 reads (33%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- LAMA1 | c.1018G>A p.E340K | Missense Mutation (SNP) | VAF 14/216 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.338); called by muse, mutect2
- LAT | c.32T>C p.L11P | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- LCMT2 | c.163G>T p.G55C | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- LGR5 | c.548G>A p.R183K | Missense Mutation (SNP) | VAF 28/204 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- LGSN | c.469A>G p.R157G | Missense Mutation (SNP) | VAF 12/145 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2
- LRP1B | c.13252T>A p.S4418T | Missense Mutation (SNP) | VAF 38/254 reads (15%) | SIFT tolerated (0.65); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- LRP2 | c.12637G>T p.A4213S | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT tolerated (0.44); PolyPhen benign (0.233); called by muse, mutect2, varscan2
- LRP5 | c.1135G>A p.D379N | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- LRRC4B | c.1426G>T p.G476C | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.536); called by muse, mutect2
- MALRD1 | c.6115G>T p.E2039* | Nonsense Mutation (SNP) | VAF 29/184 reads (16%) | called by muse, mutect2, varscan2
- MAP4K2 | c.860A>T p.D287V | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- MARCHF6 | c.2306A>G p.H769R | Missense Mutation (SNP) | VAF 17/161 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.005); called by muse, mutect2
- MBD5 | c.4394T>C p.L1465P | Missense Mutation (SNP) | VAF 45/317 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MCF2L2 | c.1204T>A p.C402S | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MED25 | c.358A>G p.T120A | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.746); called by muse, mutect2, varscan2
- MGA | c.475C>A p.H159N | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MSTO1 | c.1492G>A p.G498R | Missense Mutation (SNP) | VAF 45/265 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MUC16 | c.983C>G p.P328R | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- MUC5B | c.13741C>T p.P4581S | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MYH3 | c.5001C>A p.D1667E | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- MYH8 | c.4627A>G p.I1543V | Missense Mutation (SNP) | VAF 17/155 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MYO3B | c.3953C>G p.P1318R | Missense Mutation (SNP) | VAF 14/166 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.157); called by muse, mutect2
- NEDD4 | c.3268C>T p.L1090F (on ENST00000508342 / NM_001284338.1; = p.L671F on NM_006154.4) | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NEDD8 | c.217C>G p.L73V | Missense Mutation (SNP) | VAF 25/155 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- NEK10 | c.3029T>A p.F1010Y | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- NRXN2 | c.4412C>A p.P1471Q | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- NRXN3 | c.519C>A p.Y173* (on ENST00000557594 / NM_001272020.2; = p.Y805* on NM_004796.6) | Nonsense Mutation (SNP) | VAF 25/184 reads (14%) | called by muse, mutect2, varscan2
- OR10G2 | c.424A>T p.N142Y | Missense Mutation (SNP) | VAF 25/219 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- OR13F1 | c.878G>C p.R293P | Missense Mutation (SNP) | VAF 22/181 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- OR14C36 | c.52G>T p.V18L | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2
- OR2M3 | c.94C>A p.L32M | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.35); called by muse, mutect2, varscan2
- OR4A16 | c.439A>T p.M147L | Missense Mutation (SNP) | VAF 42/218 reads (19%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR52L1 | c.124C>A p.Q42K | Missense Mutation (SNP) | VAF 33/265 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR52L1 | c.123C>A p.S41R | Missense Mutation (SNP) | VAF 33/264 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.481); called by muse, mutect2, varscan2
- OR5H1 | c.255C>G p.F85L | Missense Mutation (SNP) | VAF 14/192 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.007); called by muse, mutect2
- OR5P3 | c.541T>C p.Y181H | Missense Mutation (SNP) | VAF 19/144 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- OR5P3 | c.374C>A p.A125D | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR6C76 | c.538C>T p.P180S | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- OTOG | c.2213G>T p.R738L | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.182); called by muse, mutect2, varscan2
- OTUD7A | c.204G>T p.Q68H | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PAGE3 | c.84+2T>C p.X28_splice | Splice Site (SNP) | VAF 8/48 reads (17%) | called by mutect2, varscan2
- PDE3A | c.2961C>G p.S987R | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PDE6G | c.114C>G p.F38L | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.973); called by mutect2, varscan2
- PDGFC | c.838T>A p.C280S | Missense Mutation (SNP) | VAF 51/268 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PDGFRL | c.158del p.K53Rfs*16 | Frame Shift Del (DEL) | VAF 21/140 reads (15%) | called by mutect2, pindel, varscan2
- PDK4 | c.1216G>T p.A406S | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PITX2 | c.432G>T p.E144D (on ENST00000354925 / NM_001204397.1; = p.E151D on NM_000325.6) | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- PKHD1L1 | c.3106C>A p.P1036T | Missense Mutation (SNP) | VAF 29/308 reads (9%) | SIFT tolerated (0.47); PolyPhen benign (0.011); called by muse, mutect2
- PKP1 | c.1637C>T p.S546L | Missense Mutation (SNP) | VAF 11/117 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); called by muse, mutect2
- PLCB3 | c.973G>A p.A325T | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- PLSCR1 | c.794G>C p.G265A | Missense Mutation (SNP) | VAF 18/146 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- POU6F1 | c.1671G>T p.E557D | Missense Mutation (SNP) | VAF 37/201 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.371); called by muse, mutect2, varscan2
- PPFIA2 | c.703G>T p.G235* | Nonsense Mutation (SNP) | VAF 14/250 reads (6%) | called by muse, mutect2
- PPP1CA | c.346G>T p.E116* | Nonsense Mutation (SNP) | VAF 25/166 reads (15%) | called by muse, mutect2, varscan2
- PRRC2A | c.2377G>A p.G793R | Missense Mutation (SNP) | VAF 28/119 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- PSTK | c.211C>G p.P71A | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.001); called by mutect2, varscan2
- PTPRN2 | c.1336A>C p.N446H | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RAB40C | c.740C>T p.A247V | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- RALYL | c.754G>A p.D252N | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.681); called by muse, mutect2, varscan2
- RELN | c.5685G>T p.M1895I | Missense Mutation (SNP) | VAF 28/170 reads (16%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2, varscan2
- RGPD3 | c.2294A>T p.K765I | Missense Mutation (SNP) | VAF 50/674 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.155); called by muse, mutect2
- RNASEH1 | c.690G>T p.W230C | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RNMT | c.682A>C p.I228L | Missense Mutation (SNP) | VAF 20/195 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.605); called by muse, mutect2
- RRN3 | c.292T>C p.S98P | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- RTL5 | c.170C>T p.P57L | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by mutect2, varscan2
- S1PR5 | c.352G>C p.A118P | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); called by muse, mutect2
- SCML2 | c.535G>T p.E179* | Nonsense Mutation (SNP) | VAF 21/58 reads (36%) | called by muse, mutect2, varscan2
- SCN11A | c.4137C>A p.N1379K | Missense Mutation (SNP) | VAF 34/195 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SELP | c.674del p.Q225Rfs*12 | Frame Shift Del (DEL) | VAF 34/98 reads (35%) | called by mutect2, pindel, varscan2
- SEZ6L | c.771G>T p.E257D | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- SEZ6L2 | c.305C>T p.P102L | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.062); called by muse, varscan2
- SHANK1 | c.5120G>A p.S1707N | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- SHROOM4 | c.1651G>A p.E551K | Missense Mutation (SNP) | VAF 36/129 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLC22A3 | c.1387dup p.T463Nfs*16 | Frame Shift Ins (INS) | VAF 26/186 reads (14%) | called by mutect2, pindel, varscan2
- SLC39A14 | c.17T>A p.L6Q | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SLITRK4 | c.310C>T p.L104F | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- SMYD4 | c.2169G>C p.Q723H | Missense Mutation (SNP) | VAF 22/193 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); called by muse, mutect2
- SPEF2 | c.454C>G p.L152V | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- SPIRE2 | c.933C>G p.H311Q | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPSB4 | c.32C>T p.S11L | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- ST8SIA6 | c.522+1G>T p.X174_splice | Splice Site (SNP) | VAF 4/20 reads (20%) | called by muse, mutect2
- STAU1 | c.855C>G p.I285M (on ENST00000371856 / NM_001319135.1; = p.I204M on NM_004602.3) | Missense Mutation (SNP) | VAF 23/162 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- STK11IP | c.1844G>C p.S615T | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT tolerated (0.97); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- STK25 | c.408G>C p.K136N | Missense Mutation (SNP) | VAF 17/143 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- STXBP5 | c.563A>G p.E188G | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- STXBP5L | c.784G>A p.G262S | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SYNPO2 | c.965C>G p.S322C | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- SYT4 | c.1179G>C p.L393F | Missense Mutation (SNP) | VAF 34/341 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.132); called by muse, mutect2
- TAF2 | c.1414G>T p.V472F | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- TAS2R3 | c.224C>G p.T75R | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- TCP11 | c.258G>C p.E86D (on ENST00000512012; = p.E24D on NM_018679.5) | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- TECR | c.479A>G p.N160S | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TG | c.1108C>T p.Q370* | Nonsense Mutation (SNP) | VAF 25/152 reads (16%) | called by muse, mutect2, varscan2
- TLE2 | c.551-2A>T p.X184_splice | Splice Site (SNP) | VAF 5/31 reads (16%) | called by muse, mutect2, varscan2
- TMC3 | c.757T>A p.S253T | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.949); called by muse, mutect2
- TMEM35A | c.278T>A p.F93Y | Missense Mutation (SNP) | VAF 35/61 reads (57%) | SIFT deleterious (0.03); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- TMEM39B | c.1285G>C p.E429Q | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TNR | c.1474C>A p.R492S | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TOGARAM2 | c.2032G>A p.V678M | Missense Mutation (SNP) | VAF 20/137 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- TRAK1 | c.2475G>C p.K825N | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT tolerated (0.47); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- TRIM37 | c.281+1G>C p.X94_splice | Splice Site (SNP) | VAF 23/127 reads (18%) | called by muse, mutect2, varscan2
- TRIM56 | c.1576G>T p.E526* | Nonsense Mutation (SNP) | VAF 10/32 reads (31%) | called by muse, mutect2, varscan2
- TRIM9 | c.431G>A p.G144D | Missense Mutation (SNP) | VAF 37/118 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- TRO | c.565G>T p.E189* | Nonsense Mutation (SNP) | VAF 28/91 reads (31%) | called by muse, mutect2, varscan2
- TSPOAP1 | c.4061C>A p.S1354Y | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.76); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- UFL1 | c.2020G>A p.E674K | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- UNC13A | c.4025A>G p.Q1342R | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- UNC5D | c.2221C>A p.L741M | Missense Mutation (SNP) | VAF 18/146 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.195); called by muse, mutect2, varscan2
- UROC1 | c.347C>A p.A116D | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- USP31 | c.860+1G>A p.X287_splice | Splice Site (SNP) | VAF 14/104 reads (13%) | called by muse, mutect2, varscan2
- USP42 | c.1496C>T p.S499L | Missense Mutation (SNP) | VAF 30/218 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.31); called by muse, mutect2, varscan2
- VCAM1 | c.662-2A>T p.X221_splice | Splice Site (SNP) | VAF 7/31 reads (23%) | called by muse, mutect2, varscan2
- VSNL1 | c.325G>A p.D109N | Missense Mutation (SNP) | VAF 68/193 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZBBX | c.2331T>A p.S777R | Missense Mutation (SNP) | VAF 18/225 reads (8%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); called by muse, mutect2
- ZBTB14 | c.27A>C p.E9D | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0.007); called by muse, mutect2
- ZCWPW2 | c.86T>C p.V29A | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- ZDHHC5 | c.1345G>C p.E449Q | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- ZG16 | c.346C>A p.R116S | Missense Mutation (SNP) | VAF 23/157 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF253 | c.683A>G p.Y228C | Missense Mutation (SNP) | VAF 34/240 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF267 | c.1826G>A p.C609Y | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.672); called by muse, mutect2, varscan2
- ZNF408 | c.82G>C p.G28R | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.36); called by muse, mutect2
- ZNF609 | c.638G>T p.G213V | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ZNF761 | c.889C>A p.P297T | Missense Mutation (SNP) | VAF 29/232 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); called by muse, mutect2, varscan2
- ZNF804A | c.1364A>G p.Y455C | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ADCY8 | c.1021C>T p.L341= | Silent (SNP) | VAF 21/124 reads (17%) | called by muse, mutect2, varscan2
- ADGRA2 | c.1869G>C p.P623= | Silent (SNP) | VAF 6/32 reads (19%) | called by muse, mutect2
- ADGRD1 | c.1281G>C p.L427= | Silent (SNP) | VAF 18/99 reads (18%) | called by muse, mutect2, varscan2
- AGMO | c.771T>C p.V257= | Silent (SNP) | VAF 6/64 reads (9%) | called by muse, mutect2, varscan2
- ANKRD34C | c.81C>A p.T27= | Silent (SNP) | VAF 14/41 reads (34%) | called by muse, mutect2, varscan2
- ASMTL | c.1278G>A p.L426= | Silent (SNP) | VAF 16/141 reads (11%) | called by muse, mutect2, varscan2
- BICDL1 | c.81C>G p.P27= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as rs1382907227; called by muse, mutect2, varscan2
- C14orf39 | c.1587A>G p.G529= | Silent (SNP) | VAF 14/81 reads (17%) | called by muse, mutect2, varscan2
- CBARP | c.558C>T p.A186= (on ENST00000382477; = p.A166= on NM_152769.3) | Silent (SNP) | VAF 18/83 reads (22%) | catalogued as rs368720347; called by muse, mutect2, varscan2
- CCDC146 | c.1989G>A p.K663= | Silent (SNP) | VAF 8/61 reads (13%) | catalogued as COSV53552745; called by muse, mutect2, varscan2
- CDHR2 | c.3216C>A p.T1072= | Silent (SNP) | VAF 16/89 reads (18%) | catalogued as COSV56139840; called by muse, mutect2, varscan2
- CEP97 | c.1150C>T p.L384= | Silent (SNP) | VAF 20/192 reads (10%) | catalogued as rs1261705606; called by muse, mutect2
- CLEC14A | c.30C>G p.L10= | Silent (SNP) | VAF 9/63 reads (14%) | called by muse, mutect2, varscan2
- COL28A1 | c.1209C>T p.P403= | Silent (SNP) | VAF 27/167 reads (16%) | catalogued as rs367990101; called by muse, mutect2, varscan2
- COL9A3 | c.105C>T p.G35= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as rs1230802919; called by muse, mutect2, varscan2
- CUBN | c.8739C>G p.S2913= | Silent (SNP) | VAF 42/226 reads (19%) | called by muse, mutect2, varscan2
- DEPTOR | c.171C>G p.L57= | Silent (SNP) | VAF 11/97 reads (11%) | catalogued as rs752543031, COSV53813254, COSV53822466; called by muse, mutect2, varscan2
- DPP6 | c.60G>T p.A20= | Silent (SNP) | VAF 25/101 reads (25%) | catalogued as rs1421158162; called by muse, mutect2, varscan2
- DYNC2I2 | c.66G>C p.A22= | Silent (SNP) | VAF 3/34 reads (9%) | catalogued as COSV65549837; called by muse, mutect2
- EP400 | c.2875C>T p.L959= | Silent (SNP) | VAF 18/104 reads (17%) | called by muse, mutect2, varscan2
- EPS8L3 | c.1098C>T p.G366= | Silent (SNP) | VAF 25/154 reads (16%) | called by muse, mutect2, varscan2
- FAM133A | c.159A>T p.T53= | Silent (SNP) | VAF 22/52 reads (42%) | called by muse, mutect2, varscan2
- FBN3 | c.8157G>T p.R2719= | Silent (SNP) | VAF 7/18 reads (39%) | called by muse, mutect2
- FNDC3B | c.1890C>A p.T630= | Silent (SNP) | VAF 30/250 reads (12%) | called by muse, mutect2, varscan2
- FOXA2 | c.1131C>G p.S377= (on ENST00000377115 / NM_153675.3; = p.S383= on NM_021784.5) | Silent (SNP) | VAF 27/136 reads (20%) | called by muse, mutect2, varscan2
- FOXI2 | c.855G>A p.Q285= | Silent (SNP) | VAF 4/21 reads (19%) | called by mutect2, varscan2
- GALNT17 | c.1644G>C p.L548= | Silent (SNP) | VAF 9/60 reads (15%) | catalogued as COSV100352845; called by muse, mutect2, varscan2
- GPR146 | c.816G>T p.G272= | Silent (SNP) | VAF 16/60 reads (27%) | catalogued as COSV52466401; called by muse, mutect2, varscan2
- GPR155 | c.1566C>T p.I522= | Silent (SNP) | VAF 12/64 reads (19%) | called by muse, mutect2
- GRIK2 | c.783C>T p.L261= | Silent (SNP) | VAF 9/43 reads (21%) | called by muse, mutect2, varscan2
- HCRTR2 | c.504G>T p.R168= | Silent (SNP) | VAF 39/273 reads (14%) | called by muse, mutect2, varscan2
- HLA-E | c.666G>A p.L222= | Silent (SNP) | VAF 21/95 reads (22%) | called by muse, mutect2, varscan2
- HNF1B | c.795G>T p.V265= | Silent (SNP) | VAF 28/165 reads (17%) | called by muse, mutect2, varscan2
- IFT140 | c.4388G>A p.*1463= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as rs1299854506; called by muse, varscan2
- INF2 | c.3664A>C p.R1222= | Silent (SNP) | VAF 4/20 reads (20%) | called by muse, mutect2, varscan2
- IRF2BP1 | c.672G>A p.G224= | Silent (SNP) | VAF 29/96 reads (30%) | called by muse, mutect2, varscan2
- JMJD1C | c.1101T>C p.L367= | Silent (SNP) | VAF 7/62 reads (11%) | called by muse, mutect2, varscan2
- KPNB1 | c.1380C>T p.L460= | Silent (SNP) | VAF 5/45 reads (11%) | catalogued as rs760686304; called by mutect2, varscan2
- LAT | c.33G>T p.L11= | Silent (SNP) | VAF 11/60 reads (18%) | called by muse, mutect2, varscan2
- LRR1 | c.1242G>A p.K414= | Silent (SNP) | VAF 13/55 reads (24%) | called by muse, mutect2, varscan2
- LY9 | c.996C>A p.A332= | Silent (SNP) | VAF 38/98 reads (39%) | catalogued as COSV54439199; called by muse, mutect2, varscan2
- MAGEB18 | c.897C>T p.F299= | Silent (SNP) | VAF 15/56 reads (27%) | catalogued as COSV57464250; called by muse, mutect2, varscan2
- MAGI2 | c.2286G>A p.R762= | Silent (SNP) | VAF 12/94 reads (13%) | called by muse, mutect2, varscan2
- MCC | c.471C>A p.L157= | Silent (SNP) | VAF 22/109 reads (20%) | catalogued as COSV68728889; called by muse, mutect2, varscan2
- MUC12 | c.15342T>C p.T5114= (on ENST00000379442; = p.T4971= on NM_001164462.1) | Silent (SNP) | VAF 5/23 reads (22%) | called by muse, mutect2, varscan2
- MYO15A | c.945A>T p.P315= | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as rs1306819727; called by muse, mutect2, varscan2
- NAV3 | c.1179C>A p.A393= | Silent (SNP) | VAF 21/118 reads (18%) | catalogued as COSV57099204; called by muse, mutect2, varscan2
- NBPF14 | c.8517T>A p.P2839= | Silent (SNP) | VAF 70/448 reads (16%) | called by muse, mutect2, varscan2
- NDUFA13 | c.360G>A p.L120= | Silent (SNP) | VAF 5/56 reads (9%) | called by muse, mutect2
- NFAT5 | c.2367T>C p.S789= | Silent (SNP) | VAF 20/111 reads (18%) | called by muse, mutect2, varscan2
- NRDC | c.801G>T p.A267= | Silent (SNP) | VAF 30/154 reads (19%) | called by muse, mutect2, varscan2
- OR13D1 | c.936G>A p.V312= | Silent (SNP) | VAF 19/65 reads (29%) | called by muse, mutect2, varscan2
- OR2M3 | c.93C>A p.V31= | Silent (SNP) | VAF 30/101 reads (30%) | catalogued as rs745743935; called by muse, mutect2, varscan2
- OR4C6 | c.123A>G p.L41= | Silent (SNP) | VAF 18/193 reads (9%) | called by muse, mutect2
- OR6C70 | c.615T>C p.L205= | Silent (SNP) | VAF 9/60 reads (15%) | called by muse, mutect2, varscan2
- OTOF | c.2454G>A p.R818= (on ENST00000272371 / NM_194248.3; = p.R71= on NM_004802.4) | Silent (SNP) | VAF 17/114 reads (15%) | called by muse, mutect2, varscan2
- PCDHB5 | c.1689G>T p.P563= | Silent (SNP) | VAF 55/188 reads (29%) | called by muse, mutect2, varscan2
- PMEL | c.651G>C p.V217= | Silent (SNP) | VAF 3/18 reads (17%) | catalogued as rs1408036943; called by muse, mutect2
- POLD1 | c.456G>C p.A152= | Silent (SNP) | VAF 6/24 reads (25%) | called by mutect2, varscan2
- PRAMEF11 | c.816C>A p.L272= | Silent (SNP) | VAF 12/138 reads (9%) | called by muse, mutect2, varscan2
- PRPF8 | c.2355G>A p.K785= | Silent (SNP) | VAF 29/115 reads (25%) | catalogued as rs1241696403; called by muse, mutect2, varscan2
- PRR12 | c.3516G>A p.E1172= (on ENST00000615927; = p.E1993= on NM_020719.3) | Silent (SNP) | VAF 10/29 reads (34%) | called by muse, varscan2
- PSG9 | c.621C>T p.V207= | Silent (SNP) | VAF 34/234 reads (15%) | catalogued as rs1218787668; called by muse, mutect2, varscan2
- RBM43 | c.138G>A p.E46= | Silent (SNP) | VAF 35/316 reads (11%) | catalogued as rs1275816286; called by muse, mutect2, varscan2
- RFX4 | c.759C>A p.G253= (on ENST00000392842 / NM_213594.3; = p.G159= on NM_032491.6) | Silent (SNP) | VAF 21/142 reads (15%) | catalogued as COSV57575326; called by muse, mutect2, varscan2
- RIT2 | c.33G>T p.P11= | Silent (SNP) | VAF 9/76 reads (12%) | catalogued as COSV99950263; called by muse, mutect2, varscan2
- RNF40 | c.1758A>G p.E586= | Silent (SNP) | VAF 17/70 reads (24%) | called by muse, mutect2, varscan2
- SCML2 | c.534G>T p.L178= | Silent (SNP) | VAF 20/55 reads (36%) | called by muse, mutect2, varscan2
- SCN2A | c.1569C>A p.V523= | Silent (SNP) | VAF 26/263 reads (10%) | called by muse, mutect2, varscan2
- SHANK1 | c.5121C>T p.S1707= | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as rs1212269661; called by muse, mutect2, varscan2
- SIX3 | c.495G>A p.L165= | Silent (SNP) | VAF 72/191 reads (38%) | called by muse, mutect2, varscan2
- SKIDA1 | c.867G>T p.A289= | Silent (SNP) | VAF 9/26 reads (35%) | called by muse, mutect2, varscan2
- SLC25A2 | c.849G>T p.L283= | Silent (SNP) | VAF 15/50 reads (30%) | called by muse, mutect2, varscan2
- SLC37A4 | c.462C>T p.I154= | Silent (SNP) | VAF 27/120 reads (23%) | called by muse, mutect2, varscan2
- SLC6A5 | c.1335A>C p.G445= | Silent (SNP) | VAF 21/196 reads (11%) | called by muse, mutect2, varscan2
- SLITRK2 | c.1800G>T p.R600= | Silent (SNP) | VAF 30/55 reads (55%) | called by muse, mutect2, varscan2
- STIM2 | c.42A>G p.G14= | Silent (SNP) | VAF 15/77 reads (19%) | called by muse, mutect2, varscan2
- SYT13 | c.1167G>A p.A389= | Silent (SNP) | VAF 24/121 reads (20%) | catalogued as rs376356915; called by muse, mutect2, varscan2
- TAS2R60 | c.870A>G p.A290= | Silent (SNP) | VAF 23/143 reads (16%) | called by muse, mutect2, varscan2
- TFCP2L1 | c.282A>G p.K94= | Silent (SNP) | VAF 16/88 reads (18%) | catalogued as rs1402015276; called by muse, mutect2, varscan2
- TMEM132C | c.3258T>C p.C1086= | Silent (SNP) | VAF 5/46 reads (11%) | called by muse, mutect2, varscan2
- TPBG | c.225C>G p.V75= | Silent (SNP) | VAF 5/20 reads (25%) | called by muse, mutect2, varscan2
- TRIM10 | c.318C>T p.I106= | Silent (SNP) | VAF 33/136 reads (24%) | called by muse, mutect2, varscan2
- TRPM4 | c.81C>T p.S27= | Silent (SNP) | VAF 15/103 reads (15%) | catalogued as rs372942488; called by muse, mutect2, varscan2
- UROC1 | c.348C>A p.A116= | Silent (SNP) | VAF 21/124 reads (17%) | called by muse, mutect2, varscan2
- WWC1 | c.582C>A p.T194= | Silent (SNP) | VAF 17/97 reads (18%) | catalogued as rs1561707618; called by muse, mutect2, varscan2
- XKR7 | c.1290C>T p.F430= | Silent (SNP) | VAF 35/110 reads (32%) | catalogued as rs1229931873; called by muse, mutect2, varscan2
- ZNF507 | c.735C>T p.Y245= | Silent (SNP) | VAF 9/61 reads (15%) | catalogued as rs145193065; called by muse, mutect2, varscan2
- ZNF567 | c.183A>T p.G61= (on ENST00000536254 / NM_001322913.1; = p.G30= on NM_152603.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 10/75 reads (13%) | called by muse, mutect2, varscan2
- ZNF835 | c.843C>A p.G281= | Silent (SNP) | VAF 16/81 reads (20%) | called by muse, mutect2, varscan2
- ZSCAN9 | c.492G>T p.L164= | Silent (SNP) | VAF 28/194 reads (14%) | catalogued as COSV52850191; called by muse, mutect2, varscan2
- AC023469.1 | n.309A>T | RNA (SNP) | VAF 28/151 reads (19%) | called by muse, mutect2, varscan2
- AC091163.2 | n.534C>A | RNA (SNP) | VAF 26/150 reads (17%) | called by muse, mutect2, varscan2
- AC244517.10 | c.36-10098T>G | Intron (SNP) | VAF 15/59 reads (25%) | called by muse, mutect2, varscan2
- ARPIN | c.-12G>A | 5'UTR (SNP) | VAF 7/67 reads (10%) | called by muse, mutect2, varscan2
- BTNL9 | c.929-93dup | Intron (INS) | VAF 21/120 reads (18%) | catalogued as rs1441672647; called by mutect2, pindel, varscan2
- C11orf80 | c.1822-46G>A | Intron (SNP) | VAF 15/56 reads (27%) | called by muse, mutect2, varscan2
- CCDC105 | chr19:15010491 G>T | 5'Flank (SNP) | VAF 12/57 reads (21%) | called by muse, mutect2, varscan2
- CDH15 | chr16:89168598 T>C | 5'Flank (SNP) | VAF 6/11 reads (55%) | catalogued as rs1393770196; called by muse, mutect2, varscan2
- CFAP221 | c.527+10427T>C | Intron (SNP) | VAF 6/64 reads (9%) | called by muse, mutect2
- CLCA3P | n.777A>C | RNA (SNP) | VAF 23/75 reads (31%) | called by muse, mutect2, varscan2
- CTSH | c.91+16G>A | Intron (SNP) | VAF 11/56 reads (20%) | called by muse, mutect2, varscan2
- CYLC2 | c.-16G>A | 5'UTR (SNP) | VAF 18/158 reads (11%) | catalogued as rs1285905109; called by muse, mutect2, varscan2
- DNAH14 | c.3052-17193A>G | Intron (SNP) | VAF 20/63 reads (32%) | catalogued as rs1395001307; called by muse, mutect2, varscan2
- EGFLAM | c.-3G>A | 5'UTR (SNP) | VAF 18/87 reads (21%) | catalogued as COSV100473668; called by muse, mutect2, varscan2
- GAA | c.1755-20G>A | Intron (SNP) | VAF 4/22 reads (18%) | catalogued as rs756761799, COSV100163018; called by mutect2, varscan2
- GLT8D2 | c.112+764C>A | Intron (SNP) | VAF 9/55 reads (16%) | called by muse, mutect2, varscan2
- GP2 | chr16:20327665 G>A | 5'Flank (SNP) | VAF 26/185 reads (14%) | called by muse, mutect2, varscan2
- GRIA1 | chr5:153489818 G>T | 5'Flank (SNP) | VAF 9/119 reads (8%) | called by muse, mutect2
- HEPACAM2 | c.79+426C>T | Intron (SNP) | VAF 6/32 reads (19%) | called by muse, mutect2, varscan2
- HERC2P3 | n.2012del | RNA (DEL) | VAF 18/188 reads (10%) | called by mutect2, pindel
- HERC2P3 | n.1587G>C | RNA (SNP) | VAF 14/178 reads (8%) | called by muse, mutect2
- IGHEP1 | n.549C>A | RNA (SNP) | VAF 24/80 reads (30%) | called by muse, mutect2, varscan2
- KANSL1L | c.2155+39T>G | Intron (SNP) | VAF 8/38 reads (21%) | called by muse, varscan2
- LPAL2 | n.348G>T | RNA (SNP) | VAF 18/65 reads (28%) | called by muse, mutect2, varscan2
- MED24 | c.560-179C>G | Intron (SNP) | VAF 14/72 reads (19%) | called by muse, mutect2
- MIR325 | n.36T>A | RNA (SNP) | VAF 29/74 reads (39%) | catalogued as rs928845462; called by muse, mutect2, varscan2
- MSR1 | c.1033+2578C>A | Intron (SNP) | VAF 19/148 reads (13%) | called by muse, mutect2, varscan2
- MTMR12 | c.81+16303C>T | Intron (SNP) | VAF 6/29 reads (21%) | called by muse, mutect2, varscan2
- NTF3 | c.-59G>A | 5'UTR (SNP) | VAF 14/74 reads (19%) | called by muse, mutect2
- PAX1 | c.287-129G>C | Intron (SNP) | VAF 16/99 reads (16%) | called by muse, varscan2
- PKD1L2 | chr16:81139667 G>T | 5'Flank (SNP) | VAF 21/53 reads (40%) | called by muse, mutect2, varscan2
- RBM3 | c.*9A>G | 3'UTR (SNP) | VAF 7/40 reads (18%) | catalogued as rs1556989500; called by muse, mutect2, varscan2
- RIC3 | c.125-13200A>T | Intron (SNP) | VAF 7/63 reads (11%) | called by muse, mutect2, varscan2
- RNU6-389P | chr7:55687896 C>T | 3'Flank (SNP) | VAF 27/169 reads (16%) | called by muse, mutect2, varscan2
- RPL8 | c.500-300A>G | Intron (SNP) | VAF 26/121 reads (21%) | called by muse, mutect2, varscan2
- SCN4B | c.*3340_*3341insA | 3'UTR (INS) | VAF 30/198 reads (15%) | called by mutect2, pindel, varscan2
- SNORD116-17 | chr15:25088081 G>T | 3'Flank (SNP) | VAF 12/54 reads (22%) | called by muse, mutect2, varscan2
- SSPOP | n.14244del | RNA (DEL) | VAF 5/21 reads (24%) | called by mutect2, pindel
- SSX6P | n.110G>C | RNA (SNP) | VAF 16/82 reads (20%) | called by muse, mutect2, varscan2
- SULF1 | c.2285-15T>C | Intron (SNP) | VAF 14/129 reads (11%) | called by muse, mutect2, varscan2
- TJP2 | c.342+28C>T | Intron (SNP) | VAF 66/220 reads (30%) | called by muse, mutect2, varscan2
- TMPRSS3 | c.*203G>C | 3'UTR (SNP) | VAF 17/64 reads (27%) | called by muse, mutect2, varscan2
- TPCN1 | c.-22G>T | 5'UTR (SNP) | VAF 32/169 reads (19%) | called by muse, mutect2, varscan2
- TRIM29 | c.*38C>T | 3'UTR (SNP) | VAF 9/32 reads (28%) | catalogued as rs1376323366; called by muse, mutect2, varscan2
- UNG | c.-46C>T | 5'UTR (SNP) | VAF 8/115 reads (7%) | called by muse, mutect2
- WT1 | chr11:32438875 T>C | 5'Flank (SNP) | VAF 18/168 reads (11%) | called by muse, mutect2
- XKR4 | c.806+36886C>A | Intron (SNP) | VAF 5/48 reads (10%) | called by muse, mutect2, varscan2
- ZEB2 | chr2:144519964 G>T | 5'Flank (SNP) | VAF 4/42 reads (10%) | called by muse, mutect2
- ZNF785 | chr16:30579829 A>T | 3'Flank (SNP) | VAF 17/88 reads (19%) | called by muse, mutect2, varscan2
